Somatic mutation profile of tumor specimen MP2PRT-PASWCA-TMP1-A (aliquot MP2PRT-PASWCA-TMP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PASWCA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,315 days).
Specimen MP2PRT-PASWCA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb0e72b1-5d66-45fa-aea5-051f50a40585.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASWCA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASWCA-NB1-A-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d01eae8b-79ac-47c9-8abd-74e4f0eac615

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 4, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRA1 | c.32G>A p.R11H | Missense Mutation (SNP) | VAF 20/390 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.255); catalogued as rs752794049, COSV101192783; called by muse, mutect2
- ATMIN | c.29C>G p.A10G | Missense Mutation (SNP) | VAF 10/219 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1371242894; called by muse, mutect2
- CFAP74 | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 46/512 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as rs777575611, COSV54565810; called by muse, mutect2
- FANCE | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 128/435 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs1002613212; called by muse, mutect2, varscan2
- OR4K1 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 61/563 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs147602385; called by muse, mutect2, varscan2
- COL9A2 | c.1127G>A p.G376E | Missense Mutation (SNP) | VAF 105/340 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CUL7 | c.4126G>C p.E1376Q | Missense Mutation (SNP) | VAF 40/546 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.864); called by muse, mutect2
- ENTPD2 | c.1376C>T p.T459I (on ENST00000355097 / NM_203468.3; = p.T436I on NM_001246.4) | Missense Mutation (SNP) | VAF 173/557 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EVA1C | c.11C>G p.P4R | Missense Mutation (SNP) | VAF 39/514 reads (8%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2
- FLRT2 | c.1345G>A p.A449T | Missense Mutation (SNP) | VAF 25/367 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.303); called by muse, mutect2
- FAM220A | c.417C>T p.D139= | Silent (SNP) | VAF 37/376 reads (10%) | catalogued as rs778571981, COSV100510726, COSV57626282; called by muse, mutect2, varscan2
- FREM2 | c.1890G>A p.R630= | Silent (SNP) | VAF 40/377 reads (11%) | called by muse, varscan2
- GATA5 | c.1119C>A p.S373= | Silent (SNP) | VAF 101/405 reads (25%) | called by muse, mutect2, varscan2
- NGEF | c.858G>A p.A286= | Silent (SNP) | VAF 31/306 reads (10%) | catalogued as rs527494178, COSV99887773; called by muse, mutect2, varscan2
- HHLA1 | c.140-1093G>A | Intron (SNP) | VAF 18/346 reads (5%) | catalogued as rs570057578; called by muse, mutect2
- TRIM67 | c.1045-12258A>G | Intron (SNP) | VAF 29/512 reads (6%) | called by muse, mutect2
